Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A463, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A463-01A (Primary Tumor).

[page 1 of 5]
F

147.5cm 68.9kg BSA: 1.68m²

Accession:

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) LEFT NECK DISSECTION:

Five lymph nodes free of tumor (0/5, level I).

Two lymph nodes free of tumor (0/2, level II).

Fifteen lymph nodes free of tumor (0/15, level III, one lymph node contains nonkeratinizing granuloma).

(B) RIGHT NECK DISSECTION:

Six lymph nodes free of tumor (0/6, level I).

Two lymph nodes free of tumor (0/2, level II).

Eleven lymph nodes free of tumor (0/11, level III).

(C) COMPOSITE RESECTION, CHIN, JAW, FLOOR OF MOUTH, TONGUE:

INVASIVE HYBRID VERRUCOUS AND CONVENTIONAL, MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 6.5 CM IN GREATEST DIMENSION.

DEPTH OF INVASION 3.2 CM.

TUMOR BORDER PREDOMINANTLY PUSHING AND FOCALLY INFILTRATIVE.

PERINEURAL AND VASCULAR INVASION ABSENT.

Lymphocytic infiltrate marked.

Mucosal and deep margins of resection negative.

ICD-O-3

CQCF: Carcinoma, squamous cell, nos 8070/3

Path: carcinoma, adenocarcinoma w/ other types of carcinoma

Site: Mouth, floor, nos C04.9

8255/3

hw 10/1/12

Entire report and diagnosis completed by

COMMENT

The bone was sent to the bone lab for decalcification and processing, results will be entered in a supplemental report.

GROSS DESCRIPTION

(A) LEFT NECK DISSECTION, LEVEL I, II, III - Received in three containers:

The container labeled left neck dissection level I - Received is a 6.5 x 5.0 x 1.8 cm aggregate of fibroadipose tissue. Dissection of this tissue reveals six possible lymph nodes ranging from 0.8 x 0.4 x 0.4 - 2.0 x 1.0 x 0.8 cm. There is also a 3.5 x 2.0 x 1.5 cm irregular portion of possible glandular tissue.

SECTION CODE: A1-A8 (from left neck dissection, level I); A1, two possible lymph nodes; A2, one possible lymph node serially sectioned; A3, one possible lymph node serially sectioned; A4, one possible lymph node serially sectioned; A5, one possible lymph node serially sectioned; A6-A8, representative sections of possible glandular tissue.

The second container is labeled left neck dissection, level II - Received is a 5.0 x 2.5 x 1.0 cm irregular portion of fibroadipose tissue. The tissue is dissected to reveal two possible lymph nodes that measure 1.8 x 1.1 x 0.5 cm and 2.5 x 1.2 x 0.5 cm.

SECTION CODE: A9-A10 (from left neck dissection level II); A9, one possible lymph node, serially sectioned; A10, one possible lymph node serially sectioned.

The container labeled left neck dissection, level III - Received is a 6.0 x 2.0 x 1.0 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal 14 possible lymph nodes ranging from 0.2 x 0.1 x 0.1 cm - 0.9 x 0.7 x 0.5 cm.

SECTION CODE: A11-A14 (from left neck dissection, level III); A11, five possible lymph nodes; A12, four possible lymph nodes; A13, three possible lymph nodes; A14, two possible lymph nodes.

(B) RIGHT NECK DISSECTION, LEVELS I, II AND III - The specimen consists of three separate specimens as levels I, II and III. Level I - A salivary gland (3.5 x 2.5 x 2.0 cm) and fibroadipose tissue (3.0 x 3.0 x 1.0 cm). Specimen is serially sectioned.

9/17/12

[page 2 of 5]
Accession:

Specimen Date/Time:

Cut surface displays a hypertrophic salivary gland with fibrocystic stroma. Six possible lymph nodes are identified ranging from 0.4 x 0.4 x 0.4 to 1.2 x 1.0 x 0.8 cm.

Level II - Fibroadipose tissue (2.5 x 2.5 x 1.0 cm). Two lymph nodes (0.5 x 0.5 x 0.4 cm and 0.8 x 0.6 x 0.5 cm) are identified.

Level III - Fibroadipose tissue (6.0 x 1.5 x 1.2 cm). Ten lymph nodes are identified ranging from 0.2 x 0.2 x 0.2 to 1.8 x 0.8 x 0.8 cm.

SECTION CODE: B1-B3 (tissue from level I); B1, five possible lymph nodes; B2, one lymph node serially sectioned; B3, representative section of salivary gland; B4, two lymph nodes from level II; B5-B10, lymph node from level III (B5, two lymph nodes; B6, four lymph nodes; B7, two lymph nodes; B8, one lymph node serially sectioned; B9, B10, one lymph node serially sectioned).

(C) COMPOSITE RESECTION CHIN, JAW, FLOOR OF MOUTH, TONGUE - An 11.0 x 9.8 x 5.4 cm mandibulectomy specimen with chin (darkly pigmented skin ellipse 15.0 x 10.0 cm), tongue (5.0 x 4.5 x 3.0 cm) and floor of mouth (6.5 x 6.0 x 3.2 cm).

A 6.5 x 6.0 x 3.2 cm tan-white exophytic mass is present in the floor of mouth invading and protruding through skin in the anterior and inferior portion, invading bone and 1.5 cm into the tongue. The tumor is 1.6 cm from the tongue resection margin, 2.7 cm from the right mandible margin and 1.8 cm from the left mandible margin.

The residual tongue is tan-brown. Remaining bone is submitted to the bone lab for margins.

SECTION CODE: C1, skin 12 to 2 o'clock, en face; C2, skin 2 to 3 o'clock, en face; C3, skin 3 to 5 o'clock, en face; C4, skin 5 to 8 o'clock, en face; C5, skin 8 to 9 o'clock, en face; C6, skin 9 to 10 to 12 o'clock, en face; C7, skin 10 to 12 o'clock, en face; C8, C9, right tongue margin, en face; C10, left tongue margin, en face; C11-C13, tumor in skin; C14, right skin and tumor; C15, left skin and tumor; C16, representative sections of right tongue and tumor; C17, C18, representative section of left tongue and tumor; C19, representative section of mid tongue.

CLINICAL HISTORY

Squamous cell carcinoma, floor of mouth.

SNOMED CODES

T-53000, T-53131, T-51200, M-11180, M-80513, M-80703

"Some tests reported here may have been developed and performance characteristics determined by:
specifically cleared or approved by the U.S. Food and Drug Administration."
Released by:

These tests have not been

Start of ADDENDUM #1

[page 3 of 5]
Page: 3

Accession:
Specimen Date/Time:

F

147.5cm 68.9kg BSA: 1.68m²

ADDENDUM

This modified report is being issued to change/add diagnosis.

Addendum completed by

DIAGNOSIS

(C) COMPOSITE RESECTION OF JAW:
HYBRID CONVENTIONAL AND VERRUCOUS CARCINOMA WITH SUPERFICIAL INVASION OF BONE.
Bony margins of resection, free of tumor.

Released by:

Start of ADDENDUM #2

[page 4 of 5]
Page: 4

F

(147.5cm 68.9kg BSA: 1.68m²)

Accession: _
Specimen Date/Time:

ADDENDUM #2

This modified report is being issued to report special studies/IHC/Molecular studies.

Addendum completed by

COMMENT

Immunoperoxidase stains show that tumor cells are strongly diffusely positive for p53, and focal rare positivity for p16. The in situ hybridization for high risk HPV is negative.

Released by:

Start of ADDENDUM #3

[page 5 of 5]
Page: 5

F

(147.5cm 68.9kg BSA: 1.68m²)

Accession:

Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

COMMENT

The diagnosis for specimen "C, Composite resection, chin, jaw, floor of mouth, tongue" :

INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED, 6.5 CM in greatest dimension.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Division of Pathology and Laboratory Medicine

Source: NCI Genomic Data Commons file 8b359ec6-c165-4430-979c-4dcd89e24356 (TCGA-CV-A463.C32FC1E6-1987-487E-90F0-9306F61FC5B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).